Somatic mutation profile of tumor specimen TCGA-CN-5361-01A (aliquot TCGA-CN-5361-01A-01D-1434-08) from TCGA case TCGA-CN-5361, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 80.4 years (29,383 days).
Specimen TCGA-CN-5361-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec12348c-c4cf-4e48-b447-4f0b761e06c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5361-10A (Blood Derived Normal), aliquot TCGA-CN-5361-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef250adb-7fee-4623-999c-40b918936bfa

The open-access MAF lists 121 somatic variants for this specimen: 80 protein-altering or splice-affecting, 40 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 40, Nonsense Mutation 9, Frame Shift Del 3, Frame Shift Ins 3, In Frame Del 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NALCN | c.2563C>T p.R855* | Nonsense Mutation (SNP) | VAF 66/142 reads (46%) | catalogued as rs376152742; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.2663C>T p.P888L (on ENST00000326724 / NM_001080395.3; = p.P785L on NM_004920.2) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100353424; called by muse, mutect2, varscan2
- ANKRD52 | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV57287644; called by muse, mutect2, varscan2
- B4GALNT3 | c.1916G>A p.S639N | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV99843786; called by muse, mutect2
- BAZ2B | c.3769A>T p.I1257F | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.449); catalogued as rs762875256, COSV99681112; called by muse, mutect2, varscan2
- BMP4 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99817067, COSV99817208; called by muse, mutect2, varscan2
- CAMKK2 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as COSV100243283; called by muse, mutect2
- CD109 | c.3161C>G p.T1054S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.179); catalogued as rs141815508, COSV54645358; called by muse, mutect2, varscan2
- CDH13 | c.351C>G p.I117M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as COSV99231809, COSV99232752; called by muse, mutect2, varscan2
- CEP19 | c.331A>T p.K111* | Nonsense Mutation (SNP) | VAF 68/411 reads (17%) | catalogued as COSV99582755; called by muse, mutect2, varscan2
- CFAP251 | c.213G>C p.K71N | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.01); catalogued as COSV99945831; called by muse, mutect2, varscan2
- CFAP54 | c.8192G>C p.R2731T | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.215); catalogued as COSV100733441, COSV61575577; called by muse, mutect2, varscan2
- CFHR5 | c.1103C>G p.S368* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as COSV99890026; called by muse, mutect2, varscan2
- COL7A1 | c.2527C>T p.R843* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as CM060937, COSV60393366, COSV60394670; called by muse, mutect2, varscan2
- CSRNP1 | c.451A>T p.M151L | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99827217; called by muse, mutect2, varscan2
- CXADR | c.1075A>G p.S359G | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV99515771; called by muse, mutect2, varscan2
- CYP24A1 | c.980C>A p.A327E | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM1510865, COSV99398709; called by muse, mutect2, varscan2
- DDB2 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747222465, COSV57038771; called by muse, mutect2, varscan2
- DGCR2 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99594144; called by muse, mutect2, varscan2
- DISP2 | c.1309C>A p.L437M | Missense Mutation (SNP) | VAF 162/803 reads (20%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.992); catalogued as COSV99140773; called by muse, varscan2
- EIF4G1 | c.841G>T p.A281S (on ENST00000346169 / NM_198241.3; = p.A85S on NM_004953.5) | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV100072452; called by muse, mutect2, varscan2
- EIF4G1 | c.842C>T p.A281V (on ENST00000346169 / NM_198241.3; = p.A85V on NM_004953.5) | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV100072454; called by muse, mutect2, varscan2
- FBXO43 | c.1022T>A p.L341* | Nonsense Mutation (SNP) | VAF 45/201 reads (22%) | catalogued as COSV101413953; called by muse, mutect2, varscan2
- GFPT1 | c.70A>C p.I24L | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.02); catalogued as COSV100623052; called by muse, mutect2, varscan2
- GIPC2 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV100883362; called by muse, mutect2, varscan2
- HEATR5B | c.5749C>T p.R1917C | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as rs752271740, COSV99250505; called by muse, mutect2, varscan2
- HILPDA | c.171C>G p.D57E | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.017); catalogued as COSV99994107; called by muse, mutect2, varscan2
- HMGA2 | c.176G>T p.S59I | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); catalogued as COSV100666647; called by muse, mutect2, varscan2
- HPS3 | c.2978A>G p.Y993C | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1432440973, COSV99224580; called by muse, mutect2, varscan2
- ITPR1 | c.1127G>A p.R376H (on ENST00000354582; = p.R361H on NM_002222.7) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as rs1260045423, CM161444, COSV57001875; called by muse, mutect2, varscan2
- KCNJ1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV60661810; called by muse, mutect2, varscan2
- KIF3C | c.1264C>A p.P422T | Missense Mutation (SNP) | VAF 65/263 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.415); catalogued as rs749446938, COSV99268053; called by muse, mutect2, varscan2
- LRRK1 | c.3181A>T p.T1061S | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.057); catalogued as COSV52619605, COSV99443963; called by muse, mutect2, varscan2
- LRRTM1 | c.8T>C p.F3S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54444154, COSV54447116; called by muse, mutect2, varscan2
- MANBA | c.1802A>G p.Y601C (on ENST00000642252; = p.Y555C on NM_005908.4) | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99899311; called by muse, mutect2, varscan2
- MAU2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.735); catalogued as COSV53239096; called by muse, mutect2, varscan2
- MCHR2 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99912900; called by muse, mutect2, varscan2
- MED14 | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 143/263 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100247706; called by muse, mutect2, varscan2
- MRGPRD | c.393C>G p.I131M | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV100482976; called by muse, mutect2
- MTF2 | c.1511C>A p.P504Q | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as COSV100940232; called by muse, mutect2, varscan2
- MYH3 | c.2531C>T p.A844V | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as rs1035337949, COSV56871032; called by muse, mutect2, varscan2
- MYPN | c.1228G>T p.V410L | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100590786; called by muse, mutect2, varscan2
- NAV1 | c.4285C>T p.P1429S | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.03); catalogued as COSV99819956; called by muse, mutect2
- NCKAP5 | c.4315A>G p.T1439A | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV100494929; called by muse, mutect2, varscan2
- NFASC | c.2875A>G p.T959A | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100366358; called by muse, varscan2
- OR5D18 | c.576T>A p.D192E | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV61738538; called by muse, mutect2, varscan2
- OSBPL6 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 86/376 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV99508905; called by muse, mutect2, varscan2
- PARD3 | c.1391T>G p.L464R | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100402325, COSV60751662; called by muse, mutect2, varscan2
- PDE3A | c.3325C>T p.Q1109* | Nonsense Mutation (SNP) | VAF 42/172 reads (24%) | catalogued as COSV62977863; called by muse, mutect2, varscan2
- PDE5A | c.500C>A p.A167D | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as rs1376822613, COSV99309415; called by muse, mutect2, varscan2
- PKHD1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.941); catalogued as COSV100585024; called by muse, mutect2, varscan2
- PNPLA8 | c.2259_2263del p.S753Rfs*9 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | catalogued as rs751849953; called by mutect2, pindel, varscan2
- RAB9B | c.473A>G p.D158G | Missense Mutation (SNP) | VAF 131/229 reads (57%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV99686171; called by muse, mutect2, varscan2
- RAPGEF2 | c.1013A>G p.N338S | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100031845; called by muse, mutect2, varscan2
- RXFP1 | c.1074C>G p.I358M | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV100314179, COSV100314351; called by muse, mutect2, varscan2
- SCN8A | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV100634423; called by muse, mutect2, varscan2
- SCO2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as rs1569521612, COSV99329898; called by muse, varscan2
- SH2D7 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs765085144, COSV99363523; called by muse, mutect2, varscan2
- SLC34A3 | c.849C>A p.T283= | Splice Region (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100746734; called by muse, mutect2, varscan2
- SMO | c.2354C>T p.S785L | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1425442829, COSV99977260; called by muse, mutect2, varscan2
- SPTBN2 | c.4076G>C p.R1359T | Missense Mutation (SNP) | VAF 84/351 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100020789; called by muse, mutect2, varscan2
- SULT4A1 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 22/94 reads (23%) | catalogued as COSV99970746; called by muse, mutect2, varscan2
- SYT5 | c.799A>G p.K267E | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1290232876, COSV100845971; called by muse, mutect2, varscan2
- TBPL1 | c.541A>G p.S181G | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV99260768; called by muse, mutect2, varscan2
- TTC37 | c.2732A>T p.Y911F | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as COSV62454999; called by muse, mutect2, varscan2
- TTC37 | c.2731T>A p.Y911N | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV100706987; called by muse, mutect2, varscan2
- ZC2HC1A | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99804601; called by muse, mutect2, varscan2
- ZFHX4 | c.2788C>A p.L930I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99259174, COSV99269370; called by muse, mutect2, varscan2
- ZMYND8 | c.2351C>T p.T784M (on ENST00000311275 / NM_001363741.2; = p.T804M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs369116353; called by muse, mutect2, varscan2
- ZNF292 | c.5677C>T p.Q1893* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | catalogued as COSV100371668; called by muse, mutect2, varscan2
- ZNF710 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs374622168; called by muse, mutect2, varscan2
- CCDC83 | c.954del p.S320Vfs*12 (on ENST00000342404 / NM_001286159.2; = p.S351Vfs*12 on NM_173556.5) | Frame Shift Del (DEL) | VAF 55/181 reads (30%) | called by mutect2, pindel, varscan2
- FCGBP | c.9453C>A p.C3151* | Nonsense Mutation (SNP) | VAF 45/212 reads (21%) | called by muse, mutect2
- IGLV3-21 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.115); called by muse, mutect2
- KIAA1217 | c.3605dup p.Q1203Pfs*11 | Frame Shift Ins (INS) | VAF 25/77 reads (32%) | called by mutect2, pindel, varscan2
- LIG3 | c.2967_2968dup p.Q990Rfs*18 | Frame Shift Ins (INS) | VAF 33/222 reads (15%) | called by mutect2, pindel, varscan2
- MASTL | c.1315_1320del p.G439_K440del | In Frame Del (DEL) | VAF 14/116 reads (12%) | called by mutect2, pindel, varscan2
- PTRH2 | c.264dup p.A89Cfs*15 | Frame Shift Ins (INS) | VAF 68/326 reads (21%) | called by mutect2, pindel, varscan2
- SLC2A4RG | c.360_362del p.L121del | In Frame Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel
- ZNF644 | c.3257_3264del p.E1086Vfs*2 | Frame Shift Del (DEL) | VAF 63/312 reads (20%) | called by mutect2, pindel, varscan2
- AGT | c.186C>G p.P62= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV100794518; called by muse, mutect2
- BRD4 | c.3372C>T p.P1124= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV99651640; called by muse, mutect2, varscan2
- CAPZA1 | c.96A>C p.V32= | Silent (SNP) | VAF 63/160 reads (39%) | catalogued as COSV99583594; called by muse, mutect2, varscan2
- CDH23 | c.6636C>A p.V2212= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV99824658; called by muse, mutect2, varscan2
- CEACAM4 | c.432C>T p.N144= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as rs781815366, COSV55732941; called by muse, mutect2, varscan2
- CLEC11A | c.345G>C p.L115= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99141718; called by muse, mutect2, varscan2
- CTNND2 | c.1143C>G p.A381= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100481748; called by muse, mutect2, varscan2
- ESR1 | c.399G>A p.E133= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99241951; called by muse, varscan2
- GLI4 | c.930C>T p.L310= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100391228; called by muse, mutect2, varscan2
- HCN1 | c.1152C>G p.T384= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs764282200, COSV100302955, COSV57511319; called by muse, mutect2, varscan2
- IGHMBP2 | c.1191G>A p.L397= | Silent (SNP) | VAF 182/627 reads (29%) | catalogued as COSV99662732; called by muse, mutect2, varscan2
- ITGB6 | c.669C>T p.F223= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99325152; called by muse, mutect2, varscan2
- KIAA1755 | c.2364C>A p.T788= | Silent (SNP) | VAF 38/136 reads (28%) | catalogued as COSV54081383, COSV99642911; called by muse, mutect2, varscan2
- KIF7 | c.2778G>A p.R926= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV99183577; called by muse, mutect2, varscan2
- LGSN | c.966T>C p.D322= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as COSV101040801; called by muse, mutect2, varscan2
- MYO6 | c.111A>G p.K37= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV100889448; called by muse, mutect2, varscan2
- NCAPG2 | c.1975C>T p.L659= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV99317767; called by muse, mutect2, varscan2
- OGDH | c.1086C>A p.T362= | Silent (SNP) | VAF 171/315 reads (54%) | catalogued as COSV99759864; called by muse, mutect2, varscan2
- OR2B6 | c.477G>A p.L159= | Silent (SNP) | VAF 45/154 reads (29%) | catalogued as COSV55128937, COSV99773879; called by muse, mutect2, varscan2
- PIK3CD | c.3036G>A p.L1012= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs374648959; called by muse, mutect2, varscan2
- PITPNM1 | c.3195C>T p.V1065= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV99653942; called by muse, varscan2
- PLK1 | c.1371C>T p.D457= | Silent (SNP) | VAF 44/130 reads (34%) | catalogued as rs773740992, COSV99892736; called by muse, mutect2, varscan2
- PRKCH | c.420C>T p.F140= | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as COSV100273918; called by muse, mutect2, varscan2
- PRSS1 | c.675G>A p.K225= | Silent (SNP) | VAF 9/221 reads (4%) | catalogued as rs375871958; called by muse, mutect2
- PRSS27 | c.798C>T p.T266= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs566068441, COSV57014183; called by muse, mutect2, varscan2
- PSME1 | c.507C>G p.G169= | Silent (SNP) | VAF 141/549 reads (26%) | catalogued as COSV99246581; called by muse, mutect2, varscan2
- ROR1 | c.315C>T p.L105= | Silent (SNP) | VAF 59/259 reads (23%) | catalogued as COSV100935771; called by muse, mutect2, varscan2
- SPINT1 | c.570C>A p.R190= | Silent (SNP) | VAF 49/201 reads (24%) | catalogued as COSV100689272; called by muse, mutect2, varscan2
- STAU1 | c.543C>G p.L181= (on ENST00000371856 / NM_001319135.1; = p.L100= on NM_004602.3) | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV100574665; called by muse, mutect2, varscan2
- SYT5 | c.798G>A p.L266= | Silent (SNP) | VAF 62/168 reads (37%) | catalogued as rs1358441339, COSV100845972; called by muse, mutect2, varscan2
- TMC4 | c.2088C>G p.V696= (on ENST00000617472 / NM_001145303.3; = p.V690= on NM_144686.4) | Silent (SNP) | VAF 43/230 reads (19%) | catalogued as COSV99652463; called by muse, mutect2, varscan2
- TNS3 | c.2445C>G p.V815= | Silent (SNP) | VAF 31/162 reads (19%) | catalogued as rs1243194163, COSV100236788; called by muse, mutect2, varscan2
- TP63 | c.345G>T p.G115= | Silent (SNP) | VAF 167/347 reads (48%) | catalogued as COSV53214839, COSV99289501; called by muse, mutect2, varscan2
- TRAJ56 | c.27G>A p.L9= | Silent (SNP) | VAF 21/109 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.45888C>T p.S15296= (on ENST00000591111; = p.S7872= on NM_003319.4) | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as rs780845171, COSV100636157; called by muse, mutect2, varscan2
- UIMC1 | c.456C>A p.L152= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV101022240; called by muse, mutect2, varscan2
- USP34 | c.1119T>C p.N373= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as COSV101277323; called by muse, mutect2, varscan2
- WDFY3 | c.2325A>T p.V775= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV99886402; called by muse, mutect2, varscan2
- ZC3H18 | c.1911G>A p.V637= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs1195027366, COSV99964595; called by muse, mutect2, varscan2
- ZNF451 | c.579C>T p.F193= | Silent (SNP) | VAF 36/143 reads (25%) | catalogued as rs553810275, COSV62599987; called by muse, mutect2, varscan2
- OR2W5 | n.376C>A | RNA (SNP) | VAF 23/105 reads (22%) | catalogued as rs764922034; called by muse, mutect2, varscan2
